Surgical pathology report (de-identified scan), TCGA case TCGA-06-0130, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0130-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSIS:

LEFT TEMPORAL LOBE: GLIOBLASTOMA MULTIFORME (MIB-1:15%).

Operation/Specimen: Left temporal lobe

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY: Multiple tissue fragments, 0.3 to 0.5 cm.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma.

all in 1-3.

MICROSCOPIC: Sections show a high grade glioma with features of glioblastoma multiforme. Immunostain for GFAP is strongly positive for the neoplastic astrocytes. Proliferation index of the tumor cells is about 15%.

Source: NCI Genomic Data Commons file 8035ca96-c99c-4e74-ad32-fa2b59246d8e (TCGA-06-0130.8DBAE41F-A953-4C98-B46D-417825E8DF65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).